Somatic mutation profile of tumor specimen C3N-00659-54 (aliquot CPT0438150002) from CPTAC case C3N-00659, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 60.2 years (21,989 days).
Specimen C3N-00659-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8631a0ec-61ba-46f5-8932-017ab740eba8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00659-50 (Buccal Cell Normal), aliquot CPT0435120001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29571340-c758-497d-99ad-4aaee52c5519

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTN1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.989); catalogued as rs369470818; called by muse, varscan2
- CARMIL2 | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1230829943, COSV100576146; called by muse, mutect2, varscan2
- LYPD6 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776243056, COSV61940086; called by muse, mutect2, varscan2
- PHLDB1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); catalogued as rs782582897, COSV100616847, COSV61880262; called by muse, mutect2, varscan2
- ZSCAN21 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs200464385, COSV52853538; called by muse, mutect2
- KLC2 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); called by mutect2, varscan2
- SMCHD1 | c.478A>T p.I160F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH7 | c.8397A>T p.A2799= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, varscan2
- MUC4 | c.12060C>T p.T4020= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs879674147; called by muse, varscan2
- NEB | c.19776T>G p.S6592= | Silent (SNP) | VAF 50/116 reads (43%) | called by muse, varscan2
- ZSWIM8 | c.2415C>T p.P805= | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as rs777450053, COSV67132583; called by muse, mutect2, varscan2
- ACSM1 | c.612-2380G>C | Intron (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
